Somatic mutation profile of cancer-model specimen HCM-BROD-0015-C25-85C (3D Organoid, passage 7; aliquot HCM-BROD-0015-C25-85C-01D-A82H-36), derived from the primary tumor of HCMI case HCM-BROD-0015-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Tumor grade: G2; Age at diagnosis: 62.6 years (22,861 days).
Specimen HCM-BROD-0015-C25-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 234785cd-5f92-42bb-af1f-123026a416b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0015-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0015-C25-10A-01D-A78W-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/761569a8-eb45-45d0-8e99-48b2abefb9f0

The open-access MAF lists 99 somatic variants for this specimen: 69 protein-altering or splice-affecting, 20 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 20, Intron 7, Nonsense Mutation 6, Frame Shift Del 2, Splice Region 2, 3'UTR 1, 3'Flank 1, 5'UTR 1, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>T p.H83Y | Missense Mutation (SNP) | VAF 528/529 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 175/412 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.560-1G>A p.X187_splice | Splice Site (SNP) | VAF 227/227 reads (100%) | hotspot (GDC flag); catalogued as rs1202793339, CD043957, CS011574, CS083991, COSV52662318, COSV52676510, COSV52683087, COSV52690533; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC006059.2 | c.1855G>A p.V619M | Missense Mutation (SNP) | VAF 233/535 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs749188442; called by muse, mutect2, varscan2
- ATAD2B | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs961584964; called by muse, mutect2, varscan2
- BPIFB2 | c.422C>G p.S141W | Missense Mutation (SNP) | VAF 23/736 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as rs868761945; called by muse, mutect2
- CHRNA1 | c.1319C>T p.A440V (on ENST00000261007 / NM_001039523.3; = p.A415V on NM_000079.4) | Missense Mutation (SNP) | VAF 144/230 reads (63%) | SIFT tolerated (1); PolyPhen possibly damaging (0.692); catalogued as rs200394375, COSV53682376; called by muse, mutect2, varscan2
- CSMD2 | c.9725C>T p.P3242L | Missense Mutation (SNP) | VAF 212/451 reads (47%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.932); catalogued as rs1214567193; called by muse, mutect2, varscan2
- DCT | c.1141G>A p.A381T | Missense Mutation (SNP) | VAF 141/279 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs772228009, COSV65468706; called by muse, mutect2, varscan2
- FGFR4 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 210/547 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52803255; called by muse, mutect2, varscan2
- FUNDC2 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 121/289 reads (42%) | catalogued as rs1471011074; called by muse, mutect2, varscan2
- GABRA4 | c.80C>T p.A27V | Missense Mutation (SNP) | VAF 141/265 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51922313; called by muse, mutect2, varscan2
- GPR45 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 244/444 reads (55%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1014931172, COSV51523771; called by muse, mutect2, varscan2
- HIP1 | c.2597C>G p.S866C | Missense Mutation (SNP) | VAF 15/353 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61190313; called by muse, mutect2
- HNRNPCL2 | c.489G>T p.K163N | Missense Mutation (SNP) | VAF 22/550 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV60404871; called by muse, mutect2
- ITGA8 | c.2274C>A p.F758L | Missense Mutation (SNP) | VAF 43/211 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65229014; called by muse, mutect2, varscan2
- KLHL34 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 278/695 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as COSV65280117; called by muse, mutect2, varscan2
- KRTAP13-2 | c.515G>T p.R172I | Missense Mutation (SNP) | VAF 80/193 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as COSV101299620, COSV101299639; called by muse, mutect2, varscan2
- MYO3B | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs371300204, COSV100512226; called by muse, mutect2, varscan2
- NBEA | c.4522C>T p.P1508S | Missense Mutation (SNP) | VAF 10/261 reads (4%) | SIFT tolerated (0.76); PolyPhen benign (0.019); catalogued as rs1204202473; called by muse, mutect2
- PCDHB3 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 224/580 reads (39%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs1554272093, COSV50582868; called by muse, mutect2, varscan2
- PWWP2A | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 16/394 reads (4%) | catalogued as COSV61047042; called by muse, mutect2
- RREB1 | c.2912C>A p.P971H | Missense Mutation (SNP) | VAF 30/514 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.365); catalogued as COSV58554521; called by muse, mutect2
- SCAMP2 | c.735C>T p.S245= | Splice Region (SNP) | VAF 105/189 reads (56%) | catalogued as rs749444721; called by muse, mutect2, varscan2
- TIAM1 | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 324/610 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV54563729, COSV99734371; called by muse, mutect2, varscan2
- TLR1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV100458774, COSV58303511; called by muse, mutect2
- VCX3B | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 136/492 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.651); catalogued as rs376250913, COSV66842319; called by muse, varscan2
- WDR87 | c.4964C>T p.A1655V | Missense Mutation (SNP) | VAF 245/410 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as rs141440839, COSV58200271; called by muse, mutect2, varscan2
- ZNF835 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 60/708 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1427176081; called by muse, mutect2
- ABHD10 | c.529A>G p.T177A | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- ANKRD13B | c.1169T>C p.I390T | Missense Mutation (SNP) | VAF 221/459 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- APOBEC3D | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 12/362 reads (3%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.658); called by muse, mutect2
- ARHGAP45 | c.650+6C>T | Splice Region (SNP) | VAF 198/361 reads (55%) | called by muse, mutect2, varscan2
- C2orf16 | c.4663G>A p.E1555K | Missense Mutation (SNP) | VAF 25/541 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- CDH24 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 38/818 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.176); called by muse, mutect2
- CDK11A | c.1183G>T p.V395L (on ENST00000378633 / NM_001313896.2; = p.V392L on NM_024011.4) | Missense Mutation (SNP) | VAF 284/611 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEACAM8 | c.14C>A p.S5* | Nonsense Mutation (SNP) | VAF 14/270 reads (5%) | called by muse, mutect2
- CRACDL | c.2150G>T p.R717M | Missense Mutation (SNP) | VAF 43/516 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CRLF1 | c.229A>G p.T77A | Missense Mutation (SNP) | VAF 293/811 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DMD | c.8750_8751insC p.K2917Nfs*8 | Frame Shift Ins (INS) | VAF 204/533 reads (38%) | called by mutect2, pindel, varscan2
- DUSP6 | c.984del p.N329Tfs*96 | Frame Shift Del (DEL) | VAF 248/345 reads (72%) | called by mutect2, pindel, varscan2
- DVL2 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EFNB3 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 78/265 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EPO | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 72/493 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HINT2 | c.405C>G p.I135M | Missense Mutation (SNP) | VAF 131/286 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); called by muse, varscan2
- HTR3D | c.10C>A p.H4N | Missense Mutation (SNP) | VAF 20/394 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen possibly damaging (0.879); called by muse, mutect2
- MAX | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 42/800 reads (5%) | called by muse, mutect2
- MELTF | c.908T>A p.F303Y | Missense Mutation (SNP) | VAF 149/307 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MEX3C | c.1528T>A p.W510R | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- MYL5 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 15/427 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- NEMF | c.2844del p.I949* | Frame Shift Del (DEL) | VAF 98/274 reads (36%) | called by mutect2, pindel, varscan2
- OLIG1 | c.712G>A p.G238S | Missense Mutation (SNP) | VAF 30/679 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.168); called by muse, mutect2
- PLEKHH1 | c.16G>A p.V6M | Missense Mutation (SNP) | VAF 18/383 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.051); called by muse, mutect2
- PRKCE | c.995C>A p.P332H | Missense Mutation (SNP) | VAF 28/299 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RBM10 | c.48T>G p.Y16* | Nonsense Mutation (SNP) | VAF 272/507 reads (54%) | called by muse, mutect2, varscan2
- RLIM | c.414T>G p.S138R | Missense Mutation (SNP) | VAF 146/326 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCN2A | c.4470G>A p.M1490I | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- SLF1 | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 127/324 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPTBN2 | c.793G>T p.D265Y | Missense Mutation (SNP) | VAF 17/333 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYNE2 | c.14160G>A p.W4720* | Nonsense Mutation (SNP) | VAF 144/295 reads (49%) | called by muse, mutect2, varscan2
- TENM3 | c.2756G>A p.R919Q | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TGFB3 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 14/382 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2
- TMEM196 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 297/633 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRPC4 | c.2417G>C p.R806T (on ENST00000379705 / NM_016179.4; = p.R811T on NM_003306.3) | Missense Mutation (SNP) | VAF 120/286 reads (42%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.096); called by muse, mutect2
- TTN | c.29827C>A p.P9943T (on ENST00000591111; = p.P9016T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | PolyPhen benign (0.202); called by muse, mutect2, varscan2
- VPS13C | c.5566G>T p.G1856W (on ENST00000644861 / NM_020821.3; = p.G1813W on NM_017684.5) | Missense Mutation (SNP) | VAF 29/284 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- ZFHX3 | c.7645C>A p.Q2549K | Missense Mutation (SNP) | VAF 22/555 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF451 | c.1205G>C p.C402S | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2
- ZNF789 | c.683C>A p.P228H | Missense Mutation (SNP) | VAF 43/270 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ACER2 | c.414C>T p.C138= | Silent (SNP) | VAF 33/233 reads (14%) | catalogued as rs764296462; called by muse, mutect2, varscan2
- ADAMTS5 | c.999C>T p.N333= | Silent (SNP) | VAF 20/538 reads (4%) | called by muse, mutect2
- APBA3 | c.873G>T p.L291= | Silent (SNP) | VAF 39/799 reads (5%) | called by muse, mutect2
- CCDC142 | c.189G>A p.V63= | Silent (SNP) | VAF 481/1026 reads (47%) | called by muse, mutect2, varscan2
- EMC1 | c.313C>A p.R105= | Silent (SNP) | VAF 54/325 reads (17%) | called by muse, mutect2, varscan2
- GOLGA6A | c.585G>A p.A195= | Silent (SNP) | VAF 179/658 reads (27%) | catalogued as rs752674779; called by muse, mutect2, varscan2
- HOXA10 | c.978C>T p.N326= | Silent (SNP) | VAF 145/304 reads (48%) | catalogued as rs1327507292; called by muse, mutect2, varscan2
- KLHL34 | c.597G>T p.L199= | Silent (SNP) | VAF 72/962 reads (7%) | called by muse, mutect2
- MKI67 | c.8673G>T p.R2891= | Silent (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- NFE2L1 | c.1986C>A p.G662= | Silent (SNP) | VAF 102/1277 reads (8%) | called by muse, mutect2
- NKRF | c.1965T>C p.D655= | Silent (SNP) | VAF 181/636 reads (28%) | called by muse, mutect2, varscan2
- NUDT11 | c.174G>A p.P58= | Silent (SNP) | VAF 431/923 reads (47%) | catalogued as rs1557326663; called by muse, mutect2, varscan2
- PGLS | c.669G>A p.P223= | Silent (SNP) | VAF 398/689 reads (58%) | catalogued as rs566960701; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1383G>T p.L461= | Silent (SNP) | VAF 24/449 reads (5%) | called by muse, mutect2
- SLC22A8 | c.1482G>A p.E494= | Silent (SNP) | VAF 72/747 reads (10%) | called by muse, mutect2
- TEX11 | c.2157T>C p.N719= (on ENST00000344304; = p.N704= on NM_031276.3) | Silent (SNP) | VAF 17/490 reads (3%) | called by muse, mutect2
- TIAM2 | c.264T>C p.G88= | Silent (SNP) | VAF 328/328 reads (100%) | catalogued as COSV100019136; called by muse, mutect2, varscan2
- TRPC4 | c.2415G>A p.P805= (on ENST00000379705 / NM_016179.4; = p.P810= on NM_003306.3) | Silent (SNP) | VAF 119/283 reads (42%) | catalogued as rs1386697561, COSV58999429, COSV59001099; called by muse, mutect2
- TTBK1 | c.2544C>T p.P848= | Silent (SNP) | VAF 479/479 reads (100%) | catalogued as rs746794094; called by muse, mutect2, varscan2
- ZAN | c.6123C>A p.I2041= | Silent (SNP) | VAF 59/387 reads (15%) | catalogued as rs779270524, COSV100770442; called by muse, mutect2, varscan2
- ANAPC15 | chr11:72107379 G>C | 3'Flank (SNP) | VAF 14/291 reads (5%) | called by muse, mutect2
- CPAMD8 | c.5567+124C>A | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2
- ELAC2 | c.1908+16G>T | Intron (SNP) | VAF 20/177 reads (11%) | catalogued as rs773964699; called by muse, mutect2, varscan2
- IGSF22 | c.*588C>G | 3'UTR (SNP) | VAF 26/756 reads (3%) | called by muse, mutect2
- IL2RG | c.115+25G>A | Intron (SNP) | VAF 121/247 reads (49%) | called by muse, mutect2, varscan2
- KCNA1 | c.-9G>A | 5'UTR (SNP) | VAF 33/272 reads (12%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8796A>G | Intron (SNP) | VAF 76/738 reads (10%) | catalogued as rs783822, COSV57106096; called by muse, varscan2
- MTA1 | c.1845+26_1845+29dup | Intron (INS) | VAF 76/226 reads (34%) | called by pindel, varscan2
- MYL6 | c.3+111G>A | Intron (SNP) | VAF 31/1068 reads (3%) | called by muse, mutect2
- SLC35A2 | c.91+25G>A | Intron (SNP) | VAF 200/507 reads (39%) | catalogued as rs1198872001; called by muse, mutect2, varscan2
